Surgical pathology report (de-identified scan), TCGA case TCGA-HW-A5KJ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-A5KJ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

Right frontal GBM.

Specimens Submitted:

- 1: Right frontal brain tumor (fs)
- 2: Right frontal brain tumor

DIAGNOSIS:

1. Right frontal brain tumor (fs):

Part # 1

TUMOR TYPE:

Anaplastic oligodendroglioma

WHO GRADE:

III

2. Right frontal brain tumor:

Part # 2

TUMOR TYPE:

Anaplastic oligodendroglioma

WHO GRADE:

III

ICD-O-3
Oligodendroglioma, anaplastic
9451/3
Path Site: Brain, Frontal lobe
CLCF Site: Brain Supratentorial NOS
C71.1
C71.0
JW 1/8/13

Note: Immunostaining for the R132H mutant of IDH1 is positive.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result

Special Stain

IMM RECUT

IDH1-H09

RECUT

NEG CONT

Comment

[page 2 of 2]
Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "Right frontal brain tumor (fs)" and consists of one piece of soft tissue measuring 0.6 x 0.5 x 0.4 cm. The specimen is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

2). The specimen is received fresh labeled, "Right frontal brain tumor", and consists of multiple pieces of gray tan friable soft tissue measuring in aggregate 3.7 x 2.0 x 1.0 cm, the largest fragment measuring 1.5 x 1.2 x 1.0 cm. A sample is submitted to The remainder of the specimen is entirely submitted.

Summary of sections:

U - undesignated

Summary:

Part 1: Right frontal brain tumor (fs)

Block		PCs
1	FSC	0

Part 2: Right frontal brain tumor

Block		PCs
5		10

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Right frontal brain tumor (fs): Glioma; favor oligodendroglioma.
PERMANENT DIAGNOSIS: same

Diagnostic Discrepancy		
ILIPAN Discrepancy		
Qual/Specimen Primary Noted		
Cut/Is Isolated		
Involved Fields		

Source: NCI Genomic Data Commons file 3c2cccab-5b58-45db-b33f-cb1df729c692 (TCGA-HW-A5KJ.5A607989-F1E0-45AD-A669-D68967ED7670.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).